Gene-level copy-number profile of tumor specimen TCGA-AG-3883-01A from TCGA case TCGA-AG-3883, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.6 years (25,415 days).
Specimen TCGA-AG-3883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.2b30336f-d979-4077-89b3-8d26527fb3c6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3883-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd50c724-a771-4ca0-998d-ac443d41f2a6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 15,965; copy number 3: 29,638; copy number 4: 12,307; copy number 5: 546; copy number 6: 610; copy number 7: 560; copy number 10: 55; copy number 11: 44; copy number 12: 6; copy number 16: 4; copy number 20: 37; copy number 37: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3883-01A-02D-0903-01): tumor purity 0.56, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 726 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:38,297,023–40,598,585, 111 genes, copy number 11–37 (broad region; genes not listed).
- chr20:22,220,554–46,736,347, 615 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
